Surgical pathology report (de-identified scan), TCGA case TCGA-3T-AA9L, project TCGA-THYM (Thymoma), tissue source site Emory University, specimen TCGA-3T-AA9L-01A (Primary Tumor).

[page 1 of 4]
-Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited. regarding

Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

ICD 0-3
Thymoma type B1 8583/3
malignant
Site ^{CCE} Thymus C37.9
path Mediastinum N05
C38.3
9/21/14

Patient Name:

MRN:

DOB:

(Age:)

Acc #:

Location:

Client:

Submitting

Phys:

Gender: F

Collected:

Received:

Reported:

Final Surgical Pathology Report

*** ADDENDUM PRESENT ***

Addendum Diagnosis

THE DIAGNOSIS REMAINS THE SAME.

Addendum Comment

The following special stains and/or immunohistochemical stains were performed:

STAIN

RESULT

Pancytokeratin

The neoplasm is predominantly lymphocytic, but has expected numbers of weakly staining epithelial cells.

Electronically Signed by

Printed by:

Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Final Pathologic Diagnosis

A. INFERIOR MEDIASTINAL MASS, VIDEO-ASSISTED THORACIC SURGERY, A1FS:

- THYMOMA, TYPE B1, LYMPHOCYTE RICH (5.0 X 3.0 X 2.0 CM), WITH DEGENERATIVE CYSTIC CHANGES AND FIBROSIS.
- THYMOMA FOCALLY EXTENDS INTO CAPSULE, AND ABUTS THE INKED SURFACE.
- SEE SYNOPTIC REPORT.

Electronically Signed by

Assisted by:

Flow Cytometry / Signed Out
Addendum / Signed Out

Synoptic Worksheet

A. Inferior mediastinal mass, FS:

Specimen:	Not specified
Procedure:	Other: Right Video-assisted thoracic surgery (VATS)
Specimen Integrity:	Intact
Specimen Weight:	27.6(g)
Tumor Size:	Greatest dimension: 5.0 cm Additional Dimension: 3.0 cm Additional Dimension: 2.0 cm
Histologic Type:	Type B1 thymoma
Tumor Extension:	Not identified
Margins:	Margin(s) involved by tumor Margin(s): peripheral
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
Regional Lymph Nodes:	Cannot be assessed Number examined: 0 Number involved: 0
Pathologic Staging for Thymomas (Modified Masaoka):	Stage IIa: Microscopic transcapsular invasion
Implants/Distant Metastasis:	Cannot be assessed
Additional Pathologic Findings:	Fibrosis Cystic changes in tumor

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [redacted] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Clinical History

Mediastinal mass. Right VATS.

Specimen(s) Received

A: Inferior mediastinal mass, FS

Gross Description

Specimen A is received fresh along with the patient's name, medical record number and as "inferior mediastinal mass, FS." The specimen consists of two fragments of soft tissue mass, the larger one measures 6.0 x 3.0 x 2.5 cm and weighs 25 gm. The specimen is already incised when received. The smaller fragment measures 2.5 x 2.0 x 0.5 cm and weighs 2.6 grams. An ill-defined encapsulated mass lesion is identified in the larger fragment and measures 5.0 x 3.0 x 2.0 cm. The cutting surface of this lesion showing yellowish and flesh color. A representative section from this ill-defined mass lesion is submitted for intraoperative consultation as "A1FS." Another ill-defined mass lesion is identified in the small fragment which measures 0.5 x 0.5 x 0.2 cm, the cutting surface of this small ill-defined mass lesion is fish-flesh. The outside surface of the entire specimen is inked blue. Sections submitted are indicated below. Dictated by

CASSETTE SUMMARY:

A1FS: A representative section of the mass lesion from the larger fragment (intraoperative consultation)
A2-A7: Representative sections of the mass lesion from the larger fragment
A8: Representative sections of the small fragment with the small mass lesion

Intraoperative Consult Diagnosis

A1FS: INFERIOR MEDIASTINAL MASS (FROZEN SECTION): CORTICAL THYMOMA VERSUS LYMPHOMA.
Frozen section results were communicated to the surgical team and were repeated back by
In at . out at

Pathologist:

Microscopic Description

Microscopic examination performed.

Flow Cytometry

Status: Signed Out

Interpretation

Flow cytometric immunophenotyping of the submitted mediastinal mass is performed using antibodies to the listed analytes. Electronic gates are placed around cell clusters displaying light scatter properties corresponding to lymphocytes (98% of total sample). The remainder of the sample is comprised of apparent debris and/or nonviable cells.

Phenotypic analysis reveals a distinct population of cells with low light scatter properties comprising approximately 98% of the total sample which express CD2, variable CD3, partial CD4, CD5, CD7, partial CD8, CD38, and CD45.

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited. regarding

Anat Path Reports

* Final Report *

Taken together, these findings demonstrate the presence of an immature T-lymphocyte population consistent with thymocytes. Clinical and laboratory correlation recommended.

REFERENCES:

Blood. 2008 Apr 15;111(8):3941-67.
Cytometry B Clin Cytom. 2007;72 Suppl 1:S14-22.
Cytometry B Clin Cytom. 2007;72 Suppl 1:S5-13.

Electronically Signed by

Assisted by:

Clinical History

Mediastinal mass

Specimen - Gross Description

Soft tan tissue measuring 1.0 x 0.7 x 0.4 cm with 10 mL of clear pink fluid identified as "mediastinal mass" is received

Analytes Tested

CD2, CD3, CD4, CD5, CD7, CD8, CD10, CD11b, CD11c, CD13, CD14, CD15, CD16, CD19, CD20, CD22, CD23, CD25, CD33, CD34, CD36, CD38, CD45, CD56, CD103, CD117, FMC7, HLA-DR, Kappa, Lambda

This test was performed at

The results of this test should not be used alone as the sole basis for diagnosis and/or treatment. These results may, however, prove useful when used in conjunction with other diagnostic procedures and clinical evaluations. Use of these results, in this manner, can be considered to fall within the scope of the practice of medicine. This test was developed and its performance characteristics determined by Drug Administration. It has not been cleared or approved by the United States Food and

Printed by:

Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file 065159e8-5cd5-446d-8d1e-64caeaf6e1e7 (TCGA-3T-AA9L.DD88E259-D9C9-4408-ACDC-95715ADD7D1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).